Surgical pathology report (de-identified scan), TCGA case TCGA-34-2600, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-34-2600-01A (Primary Tumor).

[page 1 of 3]
with persistent lung infiltrates. Precarinal lymph node measures approximately 1.2 cm. anterior to posterior, 7.0 cm. transversely, and 1.0 cm. in length. A right hilar lymph node is 1.0 cm. in short axis diameter. Left hilar lymph node is 0.5 cm. in diameter.

PRE OP DIAGNOSIS: Lung nodule.

POST OP DIAGNOSIS: Same.

PROCEDURE: Bronchoscopy with mediastinoscopy.

FINAL DIAGNOSIS

Summary Statement

The right lower lobe neoplasm is an invasive moderately differentiated squamous cell carcinoma measuring 2.0 cm. Angiolymphatic invasion is identified. No pleural invasion is seen. All margins of resection are negative for carcinoma. Lymph nodes sampled in this case show no evidence of metastatic squamous cell carcinoma. The stage is T1, N0, MX.

PART 1: LYMPH NODE, LEVEL 7, BIOPSY

ONE (1) BENIGN REACTIVE LYMPH NODE. NO CARCINOMA SEEN.

PART 2: LYMPH NODE, LEVEL 7, BIOPSY

FOUR (4) FRAGMENTS OF BENIGN LYMPHOID TISSUE. NO CARCINOMA SEEN.

PART 3: LYMPH NODE, PARATRACHEAL, BIOPSY

TWO (2) BENIGN REACTIVE LYMPH NODES. NO CARCINOMA SEEN.

PART 4: LYMPH NODE, LEVEL 3, BIOPSY

TWO (2) FRAGMENTS OF BENIGN LYMPHOID TISSUE. NO CARCINOMA SEEN.

PART 5: LYMPH NODE, STATION 9, BIOPSY

ONE (1) FRAGMENT OF BENIGN LYMPHOID TISSUE. NO CARCINOMA SEEN.

PART 6: LUNG, RIGHT LOWER LOBE, BIOPSY

INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA.

PART 7: LUNG, RIGHT LOWER LOBE, LOBECTOMY

- A. INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA (2.0 CM).
- B. ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- C. NO PLEURAL INVASION IS SEEN.
- D. ALL MARGINS OF RESECTION FREE OF TUMOR.
- E. SIX (6) BENIGN PARABRONCHIAL LYMPH NODES WITH NO CARCINOMA SEEN.
- F. STAGE: T1N0MX.

PART 8: LYMPH NODE, RIGHT LEVEL 4, BIOPSY

ELEVEN (11) BENIGN REACTIVE LYMPH NODES. NO CARCINOMA SEEN.

PART 9: LYMPH NODE, AZYGUS, BIOPSY

ONE (1) BENIGN REACTIVE LYMPH NODE. NO CARCINOMA SEEN.

PART 10: LYMPH NODE, STATION 7, BIOPSY

SIX (6) BENIGN REACTIVE LYMPH NODES. NO CARCINOMA SEEN.

COMMENT

[page 2 of 3]
GROSS DESCRIPTION

The specimen is received in multiple parts in saline.

Part 1 is labeled "Level 7 lymph node (station 7)". The specimen consists of one irregular fragment of dark, grey-black soft tissue resembling lymph node. The specimen measures 0.5 cm. in greatest dimension and is entirely submitted for frozen section diagnosis. The frozen section remnant is entirely submitted labeled 1FSA.

Part 2 is labeled "station 7 lymph node". The specimen consists of multiple irregular rubbery fragments of dark, grey-black hemorrhagic soft tissue resembling fragments of lymph node. The specimens range from 0.4-0.9 cm. in greatest dimension and are entirely submitted for frozen section diagnosis. Frozen section remnants are submitted entirely labeled 2FSA.

Part 3 is labeled "right Level 4 lymph node (paratracheal)". The specimen consists of two irregular rubbery fragments of tan-grey hemorrhagic soft tissue resembling fragments of lymph node. The specimens measure 0.6 cm. in greatest dimension and 1.2 x 1.0 x 0.5 cm., respectively. The specimens are submitted entirely for frozen section diagnosis. Frozen section remnants are submitted entirely labeled 3FSA.

Part 4 is labeled "Level 3 lymph node". The specimen consists of two irregular fragments of dark grey-black soft tissue resembling lymph node. Each measure 1.2 x 0.6 x 0.5 cm. The specimens are submitted entirely for frozen section diagnosis. Frozen section remnants are submitted entirely labeled 4FSA.

Part 5 is labeled "Level 9 lymph node". The specimen consists of one irregular fragment of rubbery, tan-grey hemorrhagic soft tissue, measuring 0.8 cm. in greatest dimension. The specimen is bisected and submitted entirely labeled 5A.

Part 6 is labeled "biopsy of right lower lobe of lung". The specimen consists of four tiny fragments of tan, hemorrhagic soft tissue, ranging from less than 0.1-0.4 cm. in greatest dimension. The specimens are submitted entirely for frozen section diagnosis. Frozen section remnants are submitted entirely labeled 6FSA.

Part 7 is received unfixed labeled "right lower lobe". It consists of a right lower lung lobe, measuring 18.0 x 15.0 x 6.5 cm and weighing 270 grams. The pleural surface is smooth, shiny, dark gray-pink with focal areas of anthracotic pigmentation and no gross evidence of adhesion. About the hilus, there are only three identifiable rubbery, gray-black lymph nodes, ranging from 0.5 to 1.4. Also about the hilus, the vascular resection margins are denoted by lines of steel surgical staples. The bronchial resection margin is patent, grossly unremarkable and submitted for frozen section diagnosis at the request of [REDACTED]. The frozen section remnant is submitted entirely labeled 7FSA. The staple lines are removed and the vascular resection margins along with hilar lymph nodes are submitted in cassette 7B. The specimen is then bisected along the long axis. The cut surface reveals spongy, gray and hemorrhagic parenchyma with a centrally located 2.0 x 7.0 x 0.1 cm lesion. This lesion is firm, pale tan and hemorrhagic and poorly circumscribed. The remainder of the cut surface is grossly unremarkable with patent vessels and bronchioles and occasional clot artifact. Representative tumor and normal tissue is frozen in bulk and digital images are taken. The pleural surface surrounding the previously described lesion is inked and additional sections are submitted as follows:

- 7C-G - tumor with inked pleural margin.
- 7H-I - tumor with adjacent normal lung.
- 7J-K - random normal lung.

Part 8 is received in saline labeled "R4 lymph nodes". It consists of an irregularly-shaped portion of tan-gray and hemorrhagic, fibroadipose soft tissue with attached rubbery, gray-black lymph nodes. The specimen measures 5.0 x 2.7 x 1.3 cm overall with the attached lymph nodes ranging from 0.5 to 1.5 x 1.5 x 1.0 cm in dimension. The specimen is separated into three equal portions, all of which are further bisected and submitted entirely labeled 8A through 8C.

[page 3 of 3]
Q. Mediastinal node group(s) involved: N / A

- | | | | |
|-------------|--------------|-------------|---------------|
| 1. Level 4R | 4. Level 7R | 7. Level 4L | 10. Level 7L |
| 2. Level 5R | 5. Level 9R | 8. Level 5L | 11. Level 9L |
| 3. Level 6R | 6. Level 10R | 9. Level 6L | 12. Level 10L |

R. Underlying disease(s): 1

- | | | |
|-------------------|--------------------------|---------------------|
| 1. Emphysema | 3. Tumorlets | 5. Asthma |
| 2. Bronchiectasis | 4. Smokers bronchiolitis | 6. Parenchymal scar |

S. TNM Stage: T 1 N 0 M X

INTRAOPERATIVE DIAGNOSIS

1A: LYMPH NODE, LEVEL 7, BIOPSY (Frozen section)

- A. BENIGN.
- B. REACTIVE LYMPH NODES. [REDACTED])

2A: LYMPH NODE, LEVEL 7, BIOPSY (Frozen section)

- A. BENIGN.
- B. REACTIVE LYMPH NODES. [REDACTED]

3A: BIOPSY, LYMPH NODES, RIGHT FORE PARATRACHEAL, BIOPSY (Frozen section)

- A. BENIGN.
- B. REACTIVE LYMPH NODES. [REDACTED]ski)

4A: LYMPH NODES, LEVEL 3, BIOPSY (Frozen section)

- A. BENIGN.
- B. REACTIVE LYMPH NODES. [REDACTED]

6A: LUNG, RIGHT LOWER LOBE, BIOPSY (Frozen section)

- A. MALIGNANT.
- B. NONSMALL CELL CARCINOMA, FAVOR SQUAMOUS CELL CARCINOMA. [REDACTED]

7A: LUNG, RIGHT LOWER LOBE, LOBECTOMY, EVALUATION OF BRONCHIAL MARGIN (Frozen section)

- A. BENIGN.
- B. BRONCHIAL MARGIN NEGATIVE FOR CARCINOMA. [REDACTED]
- [REDACTED]

Source: NCI Genomic Data Commons file 7f7b1a5e-f824-428a-b2a0-83ff959a01bb (TCGA-34-2600.CFE4E419-1C0D-4A22-8A6A-968AAACBF935.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).